Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADI, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADI-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

5/20/14

CLINICAL DIAGNOSIS: HCC

Specimen : Liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Left lateral sectionectomy

Organ: Liver, segment 7 (9.5 x 6.5 x 2.0 cm, 80.32 gm)

Lesions: A hepatic mass

Size: 2.3 x 2.0 x 1.5 cm

Cut surface: Well demarcated, yellowish tan, round and solid mass

Gross type: Multinodular confluent

Extent: Confined to the capsule

Serosal surface: Bulging by mass, but smooth

Resection margin: Very close to tumor (safety margin: less than 0.1 cm)

Remaining parenchyme: Multinodular change and firm

Representative sections are submitted.

Gross photo: Present

Blocks

T1-5, hepatic mass x 5

L, nontumorous liver parenchyme x 1

Ink key:

Resection margin: Green

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

Edmondson-steiner grade

The worst differentiation III

The major differentiation II

Histologic type: Trabecular and nesting

Cell type: Hepatic

Fatty change: Yes, focal

Cholangiocarcinoma: No

Fibrous capsule formation: No

Septum formation: No

Surgical resection margin invasion: Abut

Serosal invasion: No

Portal vein invasion: No

Vascular invasion: No

Bile duct invasion: No

Remaining liver parenchyme: Mild portal inflammation

Thyroid gland, left, aspiration, follicular cell lesion

Thyroid gland, left, aspiration, atypical cells

NOT reported. Gross:

[page 2 of 2]
liver,ectomy,Hepatocellular carcinoma
T56000, P10, M81703

DIAGNOSIS:

Liver, segment 7, left lateral sectionectomy:

Hepatocellular carcinoma, moderately differentiated

Suggestion :

Source: NCI Genomic Data Commons file c2b7552e-12ea-4896-a8f2-526efd04f40c (TCGA-DD-AADI.BA182F06-3BFF-417C-B6EE-D9FFA9B25054.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).